Somatic mutation profile of tumor specimen 0DN51M from CCDI case PBCAYR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.5 years (4,922 days).
Specimen 0DN51M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b90f90e5-d220-406a-81f5-2a6728e938f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN51G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/392b05d0-4fe2-42cc-a91f-e55dfd9ac5df

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASP10 | c.838C>T p.R280W (on ENST00000272879 / NM_032974.5; = p.R237W on NM_001230.5) | Missense Mutation (SNP) | VAF 16/610 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1351292534; called by muse, mutect2
- FAM47C | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as rs1556331631, COSV63726313; called by muse, mutect2
- PIP5K1C | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as rs2301850; called by muse, mutect2, varscan2
- TET3 | c.4828G>T p.E1610* | Nonsense Mutation (SNP) | VAF 80/1114 reads (7%) | catalogued as COSV69643205; called by muse, mutect2
- USH2A | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 112/672 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs368754739; called by muse, mutect2, varscan2
- C8G | c.454+1G>C p.X152_splice | Splice Site (SNP) | VAF 58/304 reads (19%) | called by muse, mutect2, varscan2
- REELD1 | c.895A>G p.S299G | Missense Mutation (SNP) | VAF 36/451 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2
- ATG4B | c.811+45T>C | Intron (SNP) | VAF 44/295 reads (15%) | catalogued as COSV100728836; called by muse, mutect2, varscan2
- DNPEP | c.591-36C>T | Intron (SNP) | VAF 8/236 reads (3%) | called by muse, mutect2
